Somatic mutation profile of tumor specimen TCGA-AY-6197-01A (aliquot TCGA-AY-6197-01A-11D-1719-10) from TCGA case TCGA-AY-6197, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.1 years (21,957 days).
Specimen TCGA-AY-6197-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f27b2d2e-54d3-43ee-9a04-3c67c2c6e873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-6197-10A (Blood Derived Normal), aliquot TCGA-AY-6197-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f94ec5ef-0712-4ae5-82f6-5f4c2f2d8855

The open-access MAF lists 1,307 somatic variants for this specimen: 994 protein-altering or splice-affecting, 288 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 713, Silent 288, Frame Shift Del 180, Frame Shift Ins 44, Splice Site 30, Nonsense Mutation 16, Intron 12, RNA 8, In Frame Del 5, Splice Region 5, 5'UTR 2, 3'UTR 2.

Variants (750 of 1,307; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 44/122 reads (36%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 34/69 reads (49%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMPR2 | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1085307324, CM010164, COSV101001478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.1751del p.P584Lfs*12 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | catalogued as rs886044398; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 47/101 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1035001455, COSV57246372; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 52/152 reads (34%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 11/94 reads (12%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- MEGF10 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs387907074, CM121750, COSV57250918, COSV99174792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 29/178 reads (16%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NF1 | c.1882dup p.Y628Lfs*6 | Frame Shift Ins (INS) | VAF 24/154 reads (16%) | catalogued as rs1555613558; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1897+1G>A p.X633_splice (on ENST00000273980 / NM_001163436.4; = p.X570_splice on NM_033115.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 178/466 reads (38%) | catalogued as rs374319146, CS151082, COSV56757350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AARS2 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55115470; called by muse, mutect2, varscan2
- ABCA13 | c.9499C>T p.R3167* | Nonsense Mutation (SNP) | VAF 116/289 reads (40%) | catalogued as COSV71290607; called by muse, mutect2, varscan2
- ABCA3 | c.4373T>C p.I1458T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV57055214; called by muse, mutect2
- ABCC3 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99559119; called by muse, mutect2
- ABCC4 | c.3638A>G p.E1213G | Missense Mutation (SNP) | VAF 103/391 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs1430559055, COSV100972494; called by muse, varscan2
- ABCC6 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV52744860; called by muse, mutect2, varscan2
- ABHD8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs374386420, COSV53112506; called by muse, mutect2, varscan2
- ACAA1 | c.446+2T>C p.X149_splice | Splice Site (SNP) | VAF 85/274 reads (31%) | catalogued as COSV57175467; called by muse, mutect2, varscan2
- ACACB | c.5374G>A p.G1792S | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs767320354, COSV58137121; called by muse, varscan2
- ACOT11 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs372914671; called by muse, mutect2, varscan2
- ACOT8 | c.842-2A>G p.X281_splice | Splice Site (SNP) | VAF 37/117 reads (32%) | catalogued as COSV54170052; called by muse, varscan2
- ACTL8 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs372742900; called by muse, mutect2, varscan2
- ACTL9 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV61006172; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 124/166 reads (75%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61702605; called by muse, mutect2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 64/188 reads (34%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAM7 | c.2264+1G>A p.X755_splice | Splice Site (SNP) | VAF 68/213 reads (32%) | catalogued as COSV51541586; called by muse, mutect2, varscan2
- ADAMTS16 | c.2425T>C p.Y809H | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as COSV56977438; called by muse, mutect2, varscan2
- ADAMTS19 | c.1529A>G p.H510R | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1373678634, COSV50756142; called by muse, mutect2, varscan2
- ADAMTS20 | c.4033G>A p.A1345T | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV67133349; called by muse, mutect2, varscan2
- ADAT1 | c.91T>C p.W31R | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV57187018; called by muse, mutect2
- ADCY4 | c.1582del p.R528Gfs*3 | Frame Shift Del (DEL) | VAF 43/140 reads (31%) | catalogued as rs746788867; called by mutect2, pindel, varscan2
- ADCY5 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1221027778, COSV59196136; called by muse, mutect2, varscan2
- ADGRD1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55448155; called by muse, mutect2, varscan2
- ADGRF5 | c.3140C>T p.S1047F | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51935464; called by muse, mutect2, varscan2
- ADGRG1 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65635854; called by muse, mutect2, varscan2
- ADGRL3 | c.2056G>T p.A686S (on ENST00000506720 / NM_001322402.2; = p.A618S on NM_015236.6) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as rs1408807293, COSV63368329; called by muse, varscan2
- ADGRV1 | c.3437A>G p.Y1146C | Missense Mutation (SNP) | VAF 121/694 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV67987720; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- ADRA1D | c.1127A>G p.Q376R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV65241181; called by muse, mutect2, varscan2
- AFDN | c.1967C>A p.P656H | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV60046831; called by muse, mutect2, varscan2
- AFF1 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs760065530, COSV57120899; called by muse, mutect2, varscan2
- AGBL5 | c.2437del p.R813Gfs*68 | Frame Shift Del (DEL) | VAF 51/152 reads (34%) | catalogued as rs759542168; called by mutect2, pindel, varscan2
- AGL | c.2158-1G>T p.X720_splice | Splice Site (SNP) | VAF 41/282 reads (15%) | catalogued as rs886043990, COSV54053871; called by muse, mutect2, varscan2
- AKAP13 | c.8378G>A p.R2793H (on ENST00000394518 / NM_007200.5; = p.R2797H on NM_006738.6) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368581372, COSV100773750; called by muse, mutect2, varscan2
- AL136295.1 | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55780360; called by muse, mutect2, varscan2
- ALCAM | c.1728A>C p.E576D | Missense Mutation (SNP) | VAF 125/276 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV60249935; called by muse, mutect2, varscan2
- ALDH1A2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179237166, COSV51083375; called by muse, mutect2, varscan2
- ALDH1B1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs775731660, COSV66619652, COSV66619678; called by muse, mutect2, varscan2
- ALDH1L2 | c.2606A>G p.Y869C | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV51556794; called by muse, mutect2, varscan2
- ALDH1L2 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV51556808; called by muse, mutect2
- ALG1 | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 77/611 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as COSV52158029; called by muse, mutect2, varscan2
- ALOX12 | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as COSV99278088; called by muse, mutect2, varscan2
- ALPK2 | c.6090G>T p.E2030D | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV64493919; called by muse, mutect2, varscan2
- AMOT | c.2317C>T p.P773S (on ENST00000371959 / NM_001113490.1; = p.P364S on NM_133265.3) | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV59064619; called by muse, mutect2, varscan2
- ANAPC2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100119267, COSV60570549; called by muse, mutect2
- ANGEL1 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 88/114 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51873889; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 301/802 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51850368; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.498T>A p.F166L | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.931); catalogued as COSV99783254; called by muse, mutect2
- ANKRD11 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1301722354, COSV56363190; called by muse, mutect2, varscan2
- ANKRD34A | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as COSV60161212; called by muse, mutect2, varscan2
- ANKRD52 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768397824, COSV57282216; called by muse, mutect2, varscan2
- ANKRD7 | c.227T>G p.L76R | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as COSV54555212; called by muse, mutect2
- ANO2 | c.2480G>A p.R827H (on ENST00000356134 / NM_001278597.3; = p.R831H on NM_001278596.3) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs569255760, COSV59011733; called by muse, mutect2, varscan2
- ANOS1 | c.1076T>C p.V359A | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV99390855; called by muse, mutect2
- ANXA13 | c.896T>G p.V299G | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99146111; called by muse, mutect2
- AP1M1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52227091; called by muse, mutect2, varscan2
- AP1M2 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.029); catalogued as COSV51567664; called by muse, mutect2, varscan2
- AP1S3 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100525232; called by muse, mutect2
- APBA3 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV57462915; called by muse, mutect2, varscan2
- APC | c.5113A>C p.T1705P | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57351820, COSV57362893, COSV99967452; called by muse, mutect2, varscan2
- APLNR | c.781T>C p.W261R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951432; called by muse, mutect2
- APOBEC3C | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99328935; called by muse, varscan2
- ARHGAP1 | c.710del p.L237Rfs*135 | Frame Shift Del (DEL) | VAF 29/86 reads (34%) | catalogued as rs754492553, COSV61735193; called by mutect2, pindel, varscan2
- ARHGAP30 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 117/881 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV63517181; called by muse, mutect2, varscan2
- ARHGAP4 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 96/120 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63132507; called by muse, mutect2, varscan2
- ARHGEF7 | c.629T>C p.V210A (on ENST00000375741 / NM_001113511.2; = p.V32A on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV54545112; called by muse, mutect2, varscan2
- ARID1A | c.6706C>T p.R2236C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs763691986, COSV61371693, COSV61388565; called by muse, mutect2, varscan2
- ARL6 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60117870; called by muse, mutect2, varscan2
- ASAP3 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60875477; called by muse, mutect2, varscan2
- ASNSD1 | c.414del p.F138Lfs*78 | Frame Shift Del (DEL) | VAF 74/579 reads (13%) | catalogued as rs759722534; called by mutect2, varscan2
- ASXL3 | c.4841T>C p.M1614T | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52469396; called by muse, mutect2, varscan2
- ATAD2 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 28/271 reads (10%) | catalogued as COSV54882023; called by muse, mutect2, varscan2
- ATAD3B | c.890G>A p.R297Q (on ENST00000308647; = p.R403Q on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/491 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs770117658, COSV100426438; called by muse, mutect2, varscan2
- ATCAY | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56656922; called by muse, mutect2, varscan2
- ATG13 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100365737; called by muse, mutect2
- ATP2B3 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 105/132 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV54850842; called by muse, mutect2, varscan2
- ATP8B1 | c.2633A>G p.D878G | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV52176849; called by muse, mutect2, varscan2
- AXL | c.1340C>T p.S447L (on ENST00000301178 / NM_021913.5; = p.S438L on NM_001699.6) | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs774958319, COSV56566660; called by muse, mutect2, varscan2
- B4GALNT1 | c.1481G>T p.R494M | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV100247120; called by muse, mutect2
- BANK1 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV59844652; called by muse, mutect2, varscan2
- BCO2 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV63063725; called by muse, mutect2, varscan2
- BICD2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs774220760, COSV63549255; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 90/268 reads (34%) | catalogued as rs755506199; called by mutect2, varscan2
- BIN1 | c.550del p.Q184Sfs*12 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as COSV99387241; called by mutect2, pindel, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 108/216 reads (50%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPNT1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776487679, COSV59040258; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 64/162 reads (40%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD9 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs748289899, COSV60247246; called by muse, mutect2, varscan2
- C12orf66 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV61323594; called by muse, mutect2, varscan2
- C1QTNF5 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321344741, COSV60990746; called by muse, mutect2, varscan2
- C1orf21 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV52407358; called by muse, mutect2, varscan2
- C2orf49 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs368281845, COSV51528037; called by muse, mutect2, varscan2
- C6orf136 | c.695G>A p.R232Q (on ENST00000376473 / NM_001109938.3; = p.R98Q on NM_145029.4) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757707277, COSV53314681; called by muse, mutect2, varscan2
- CAB39L | c.10dup p.M4Nfs*5 | Frame Shift Ins (INS) | VAF 144/620 reads (23%) | catalogued as rs1270111731; called by mutect2, varscan2
- CACNA1C | c.1076G>A p.C359Y | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100218592; called by muse, mutect2
- CACNA1H | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61993604; called by muse, mutect2
- CACNA2D2 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs142559701; called by muse, mutect2, varscan2
- CADM3 | c.914T>C p.M305T (on ENST00000368125 / NM_001127173.3; = p.M339T on NM_021189.5) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as COSV63685907; called by muse, mutect2, varscan2
- CALHM2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV53296254; called by muse, mutect2, varscan2
- CALML4 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51117043; called by muse, mutect2, varscan2
- CAMTA2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs771633938, COSV61835622; called by muse, mutect2, varscan2
- CAND2 | c.934C>A p.P312T (on ENST00000456430 / NM_001162499.2; = p.P219T on NM_012298.3) | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs940285548, COSV55991081; called by muse, mutect2, varscan2
- CARD11 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.175); catalogued as COSV62718033; called by muse, mutect2, varscan2
- CASP4 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 214/518 reads (41%) | catalogued as COSV67744516; called by muse, mutect2, varscan2
- CASQ1 | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV100850142; called by muse, mutect2, varscan2
- CATSPERD | c.1635-1G>T p.X545_splice | Splice Site (SNP) | VAF 23/173 reads (13%) | catalogued as COSV58465785; called by muse, mutect2, varscan2
- CBL | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 123/518 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99876236; called by muse, mutect2, varscan2
- CBLL1 | c.182-2A>G p.X61_splice | Splice Site (SNP) | VAF 20/140 reads (14%) | catalogued as COSV56029467; called by muse, varscan2
- CBX8 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV53936761; called by muse, mutect2
- CCDC151 | c.1628A>G p.N543S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62698213; called by muse, mutect2, varscan2
- CCDC42 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53449033; called by muse, mutect2, varscan2
- CCDC57 | c.1517G>T p.R506M | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.819); catalogued as COSV58935662; called by muse, mutect2, varscan2
- CD276 | c.1181T>C p.V394A (on ENST00000318443 / NM_001024736.2; = p.V176A on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100573355; called by muse, mutect2
- CD40 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 126/317 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV64847913; called by muse, mutect2, varscan2
- CD9 | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs777932393, COSV50530723; called by muse, mutect2, varscan2
- CDCA2 | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV100398864; called by muse, mutect2
- CDH15 | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs768627306, COSV57025111; called by muse, mutect2, varscan2
- CDH7 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV59887977; called by muse, mutect2, varscan2
- CDHR5 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51564505; called by muse, mutect2, varscan2
- CDK5 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV52523304; called by muse, mutect2, varscan2
- CDKL3 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 153/430 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54742525; called by muse, mutect2, varscan2
- CDRT1 | c.1003T>C p.S335P | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs776512385, COSV55412082; called by muse, mutect2, varscan2
- CELSR2 | c.6757C>T p.R2253C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs780149025, COSV54773882, COSV54773974; called by muse, mutect2, varscan2
- CELSR3 | c.6504G>T p.Q2168H | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV50886002; called by muse, mutect2, varscan2
- CELSR3 | c.4264C>T p.R1422C | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs555608365, COSV50886281; called by muse, mutect2, varscan2
- CENPT | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV54650344; called by muse, mutect2, varscan2
- CES2 | c.423G>T p.P141= | Splice Region (SNP) | VAF 45/97 reads (46%) | catalogued as COSV57697090; called by muse, mutect2, varscan2
- CES5A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51867410; called by muse, mutect2, varscan2
- CFAP221 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 141/392 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs556658192, COSV54658547; called by muse, mutect2, varscan2
- CFAP47 | c.2004A>G p.I668M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.597); catalogued as COSV52886540; called by muse, mutect2, varscan2
- CHAMP1 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63522576; called by muse, mutect2, varscan2
- CHD6 | c.7718C>T p.P2573L | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV64691761; called by muse, mutect2, varscan2
- CHD6 | c.7340G>A p.R2447Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs759871391, COSV64691766; called by muse, mutect2, varscan2
- CHMP6 | c.260T>C p.M87T | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs146664368; called by muse, mutect2, varscan2
- CHPF | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1354759404, COSV60535141; called by muse, mutect2, varscan2
- CHRNB3 | c.457T>A p.C153S | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51495576; called by muse, mutect2, varscan2
- CHRNB3 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51495584; called by muse, mutect2, varscan2
- CIDEB | c.208A>T p.N70Y | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51866346; called by muse, mutect2, varscan2
- CIP2A | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs368646955; called by muse, mutect2, varscan2
- CITED2 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs762473911, COSV62726626; called by muse, mutect2
- CLDN16 | c.114+2T>C p.X38_splice | Splice Site (SNP) | VAF 16/360 reads (4%) | catalogued as COSV99290154; called by muse, mutect2
- CNTLN | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs369975567, COSV52084525; called by muse, mutect2, varscan2
- CNTN1 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV61640987; called by muse, mutect2, varscan2
- CNTNAP4 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV56685623; called by muse, mutect2
- CNTNAP4 | c.2086A>G p.T696A | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV56685637; called by muse, mutect2, varscan2
- COL11A1 | c.5081T>C p.V1694A | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1404456235, COSV62186384; called by muse, mutect2, varscan2
- COL12A1 | c.7703T>C p.L2568P | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV59398281; called by muse, mutect2, varscan2
- COL15A1 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV66646203; called by muse, mutect2, varscan2
- COL1A1 | c.3272G>A p.G1091D | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56806332; called by muse, mutect2
- COL21A1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 184/495 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1009121320, COSV55158368; called by muse, mutect2, varscan2
- COL28A1 | c.2761A>G p.N921D | Missense Mutation (SNP) | VAF 104/444 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV68082752; called by muse, mutect2, varscan2
- CPA5 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316560901, COSV100812300; called by muse, mutect2
- CPNE7 | c.1126A>T p.M376L | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV52013498; called by muse, mutect2, varscan2
- CRPPA | c.1289C>A p.A430D (on ENST00000407010 / NM_001368197.1; = p.A380D on NM_001101417.4) | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV67906668; called by muse, mutect2, varscan2
- CSMD3 | c.580T>A p.F194I | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1189222200, COSV99833678; called by muse, mutect2
- CTCF | c.2070del p.E691Sfs*30 | Frame Shift Del (DEL) | VAF 89/245 reads (36%) | catalogued as rs1400980130; called by mutect2, pindel, varscan2
- CTTNBP2NL | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs563686739, COSV54745142; called by muse, mutect2, varscan2
- CUL5 | c.1311+2T>C p.X437_splice | Splice Site (SNP) | VAF 28/246 reads (11%) | catalogued as COSV63230120; called by muse, mutect2, varscan2
- CUL7 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.629); catalogued as COSV54818420; called by muse, mutect2, varscan2
- CUX2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1364584717, COSV55636062; called by muse, mutect2, varscan2
- CXCL5 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756143598, COSV56018707; called by muse, mutect2, varscan2
- CXCL9 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs764068063, COSV53579106; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 22/227 reads (10%) | catalogued as rs745836350; called by mutect2, varscan2
- CYFIP2 | c.1975C>T p.R659* (on ENST00000616178 / NM_001291722.2; = p.R634* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 55/150 reads (37%) | catalogued as COSV59034688, COSV59036329; called by muse, mutect2, varscan2
- CYP19A1 | c.1417A>T p.K473* | Nonsense Mutation (SNP) | VAF 120/315 reads (38%) | catalogued as COSV53059967; called by muse, mutect2, varscan2
- CYP20A1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs778631685, COSV61909692; called by muse, mutect2, varscan2
- DAG1 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs544574838, COSV58182867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF4L2 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100150865; called by muse, mutect2
- DCAF4L2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 172/574 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1160347234, COSV60479615, COSV60480142; called by muse, mutect2, varscan2
- DCAF5 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs751152443, COSV58461031; called by muse, mutect2, varscan2
- DCTN2 | c.599del p.P200Qfs*32 (on ENST00000548249 / NM_001261413.2; = p.P205Qfs*32 on NM_006400.4) | Frame Shift Del (DEL) | VAF 30/300 reads (10%) | catalogued as rs745744034; called by mutect2, pindel, varscan2
- DDX23 | c.1658G>T p.R553M | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56398987; called by muse, mutect2, varscan2
- DDX6 | c.1159A>G p.N387D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99870327; called by muse, mutect2, varscan2
- DENND2C | c.1766A>G p.E589G (on ENST00000393274 / NM_001256404.2; = p.E532G on NM_198459.4) | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV67922206; called by muse, mutect2, varscan2
- DENND5A | c.2857+2T>C p.X953_splice | Splice Site (SNP) | VAF 38/95 reads (40%) | catalogued as COSV60234747; called by muse, mutect2, varscan2
- DEPDC5 | c.3499G>A p.D1167N (on ENST00000400246; = p.D1236N on NM_014662.5) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1340279120, COSV56700534; called by muse, mutect2, varscan2
- DERL1 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52365114; called by muse, mutect2, varscan2
- DHRS9 | c.669dup p.L224Tfs*21 | Frame Shift Ins (INS) | VAF 30/140 reads (21%) | catalogued as rs756920263; called by mutect2, varscan2
- DIDO1 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 148/393 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762612611, COSV56625614; called by muse, mutect2, varscan2
- DIPK1C | c.992A>C p.D331A | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59725421; called by muse, mutect2
- DIS3L | c.2681G>T p.R894M (on ENST00000319212 / NM_001143688.3; = p.R811M on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV56019394, COSV56020216; called by muse, mutect2, varscan2
- DKC1 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV65778283; called by muse, mutect2
- DKK3 | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100485016; called by muse, mutect2, varscan2
- DLGAP1 | c.1153A>G p.T385A | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as rs1191630946, COSV59812093; called by muse, mutect2, varscan2
- DMXL2 | c.5161T>C p.F1721L | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51848534; called by muse, mutect2, varscan2
- DNAH1 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs749446487, COSV70230279; called by muse, mutect2, varscan2
- DNAH1 | c.4031A>C p.K1344T | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101325695; called by muse, mutect2
- DNAH11 | c.1894T>C p.S632P | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV60961179; called by muse, mutect2, varscan2
- DNAH2 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs202126157, COSV50015452; called by muse, mutect2, varscan2
- DNAH8 | c.10037G>A p.C3346Y | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59455009; called by muse, mutect2
- DNAJB8 | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV59878957; called by muse, mutect2, varscan2
- DNAJC11 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.453); catalogued as rs745627956, COSV50011007; called by muse, mutect2, varscan2
- DOCK10 | c.2192C>T p.T731I | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV51417875; called by muse, mutect2, varscan2
- DOCK2 | c.2554+2T>C p.X852_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | catalogued as COSV56957565, COSV56964449; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 102/313 reads (33%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK8 | c.4583C>T p.A1528V | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV66620471; called by muse, mutect2, varscan2
- DPP3 | c.440G>A p.C147Y | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV64757060; called by muse, mutect2, varscan2
- DPY19L4 | c.1952T>C p.V651A | Missense Mutation (SNP) | VAF 56/590 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.089); catalogued as COSV101363270; called by muse, mutect2
- DRC1 | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99717614; called by mutect2, varscan2
- DSCAM | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 160/435 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV68025674; called by muse, mutect2, varscan2
- DST | c.16343C>T p.T5448M (on ENST00000361203 / NM_001374722.1; = p.T3036M on NM_015548.5) | Missense Mutation (SNP) | VAF 135/343 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1235729866, COSV55021213; called by muse, mutect2, varscan2
- DST | c.6393T>A p.S2131R | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99755555; called by muse, mutect2, varscan2
- DVL2 | c.1522C>A p.L508I | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as COSV50036629; called by muse, mutect2, varscan2
- DYNC1H1 | c.3676C>T p.R1226W | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1000725714, COSV64134252; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 95/271 reads (35%) | catalogued as rs772082432; called by mutect2, varscan2
- DYRK4 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372119957; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 66/226 reads (29%) | catalogued as rs369293935; called by mutect2, varscan2
- ECI1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 51/113 reads (45%) | catalogued as rs746451005, COSV57039552; called by muse, mutect2, varscan2
- EDAR | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558793513, COSV51503957; called by muse, mutect2, varscan2
- EDAR | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51502975, COSV51503971; called by muse, mutect2, varscan2
- EEF1AKNMT | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 134/332 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763335545, COSV100675750; called by muse, mutect2, varscan2
- EFCAB3 | c.323T>C p.F108S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59502753; called by muse, mutect2, varscan2
- EGFLAM | c.1097del p.G366Afs*32 | Frame Shift Del (DEL) | VAF 57/170 reads (34%) | catalogued as rs773311790; called by mutect2, pindel, varscan2
- EGLN2 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs776147138, COSV58280342; called by muse, varscan2
- ELF4 | c.1537A>G p.S513G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.248); catalogued as COSV100257347; called by muse, mutect2, varscan2
- ELF4 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 48/67 reads (72%) | catalogued as rs991949946, COSV57453176; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 23/91 reads (25%) | catalogued as rs769175197; called by mutect2, varscan2
- ENTPD7 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65112318; called by muse, mutect2, varscan2
- EPB41 | c.1744del p.T582Qfs*11 (on ENST00000343067 / NM_001166005.2; = p.T373Qfs*11 on NM_004437.4) | Frame Shift Del (DEL) | VAF 85/413 reads (21%) | catalogued as COSV58042400; called by mutect2, pindel, varscan2
- EPHA4 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 145/390 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV56036119; called by muse, mutect2, varscan2
- ERAL1 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV54740083; called by muse, mutect2, varscan2
- ERBB3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1354914975, COSV57247317; called by muse, mutect2, varscan2
- ERCC4 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 138/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202186213, COSV61311563, COSV61313862; called by muse, mutect2, varscan2
- ERCC6 | c.3848A>G p.E1283G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63391238; called by muse, mutect2
- ERI3 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV64832088; called by muse, mutect2, varscan2
- ERICH1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.991); catalogued as rs779103293, COSV50638711; called by muse, mutect2, varscan2
- ESCO2 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs556131901, COSV59413836, COSV59416257; called by muse, mutect2, varscan2
- ESM1 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67318443; called by muse, mutect2
- ESPL1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV57760094; called by muse, mutect2, varscan2
- ESRP1 | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64410474; called by muse, mutect2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 28/250 reads (11%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- EXOC1 | c.1298T>C p.M433T | Missense Mutation (SNP) | VAF 41/787 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100637859; called by muse, mutect2
- EXOC3L4 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs373799053; called by muse, mutect2, varscan2
- EXOSC10 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58665976; called by muse, mutect2, varscan2
- EXT1 | c.1538T>C p.I513T | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65480991; called by muse, mutect2
- EZH2 | c.1715C>T p.P572L (on ENST00000460911 / NM_001203247.2; = p.P577L on NM_004456.5) | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1554486390, COSV57449917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F13A1 | c.1156C>A p.L386I | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53560569; called by muse, mutect2, varscan2
- F8 | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1270074209, CM053260, COSV64274716; called by muse, mutect2, varscan2
- FAH | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV55722067; called by muse, mutect2
- FAM13A | c.2799A>T p.K933N | Missense Mutation (SNP) | VAF 30/497 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV99983606; called by muse, mutect2
- FAM160B2 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs1190918716, COSV57158964; called by muse, mutect2, varscan2
- FAM161A | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 227/594 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56766661; called by muse, mutect2, varscan2
- FAM83C | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs1267976399, COSV65583446; called by muse, mutect2, varscan2
- FAM83E | c.889dup p.Q297Pfs*33 | Frame Shift Ins (INS) | VAF 27/72 reads (38%) | catalogued as rs773971919; called by mutect2, varscan2
- FANCB | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 76/95 reads (80%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60760330; called by muse, mutect2, varscan2
- FASN | c.1236del p.A413Hfs*39 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as COSV60760319; called by mutect2, varscan2
- FAT1 | c.9215T>C p.L3072P | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV71674686; called by muse, mutect2, varscan2
- FAT4 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs1227990108, COSV67881152; called by muse, mutect2, varscan2
- FBXO40 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 104/243 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144132932; called by muse, mutect2, varscan2
- FFAR4 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 187/517 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101012268; called by muse, mutect2, varscan2
- FGF18 | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51126810; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 33/178 reads (19%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLG | c.907A>G p.S303G | Missense Mutation (SNP) | VAF 147/628 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100911548; called by muse, varscan2
- FLRT1 | c.1928G>A p.G643D | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs888654575, COSV55362365; called by muse, mutect2, varscan2
- FNIP1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs199669129, COSV100330429; called by muse, mutect2, varscan2
- FOXG1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57397623; called by muse, mutect2, varscan2
- FOXL2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57727727; called by muse, mutect2, varscan2
- FPR1 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV59052526; called by muse, mutect2, varscan2
- FRAS1 | c.4378A>C p.T1460P | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.352); catalogued as COSV53619279; called by muse, mutect2
- FREM2 | c.1052C>A p.P351H | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV54841223; called by muse, mutect2, varscan2
- FRMD4B | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.101); catalogued as COSV68330826; called by muse, mutect2, varscan2
- FRS2 | c.413-1G>A p.X138_splice | Splice Site (SNP) | VAF 43/118 reads (36%) | catalogued as COSV54726881; called by muse, mutect2, varscan2
- FRY | c.5918C>A p.A1973D | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV66572149; called by muse, mutect2, varscan2
- FSCN3 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.759); catalogued as rs758665140, COSV56170546; called by muse, mutect2, varscan2
- FSTL4 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 131/364 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV54770606; called by muse, mutect2, varscan2
- FUT1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.548); catalogued as COSV59568577; called by muse, mutect2, varscan2
- FXN | c.95C>T p.A32V (on ENST00000377270; = p.A107V on NM_000144.5) | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV66009935; called by muse, mutect2, varscan2
- FYCO1 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1559462086, COSV56116893; called by muse, mutect2
- GABBR1 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63543041; called by muse, mutect2, varscan2
- GADL1 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as COSV56980338; called by muse, mutect2, varscan2
- GAPVD1 | c.2973A>G p.I991M (on ENST00000394104; = p.I1018M on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.948); catalogued as COSV52924022; called by muse, mutect2, varscan2
- GAPVD1 | c.3719G>A p.R1240Q (on ENST00000394104; = p.R1249Q on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV52924034; called by muse, mutect2, varscan2
- GCNT1 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.498); catalogued as COSV65057946; called by muse, mutect2, varscan2
- GEMIN4 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373624818; called by muse, mutect2, varscan2
- GEMIN5 | c.3005A>G p.H1002R | Missense Mutation (SNP) | VAF 57/279 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.559); catalogued as rs1473978726, COSV53561469; called by muse, mutect2, varscan2
- GFM1 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51833333; called by muse, mutect2, varscan2
- GH2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs773390813, COSV60427069; called by muse, mutect2, varscan2
- GHITM | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 72/555 reads (13%) | catalogued as COSV64538686; called by muse, mutect2, varscan2
- GHSR | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs202007365, COSV53840083; called by muse, mutect2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 32/178 reads (18%) | catalogued as rs763147690; called by mutect2, varscan2
- GLB1 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56564927; called by muse, mutect2, varscan2
- GMCL1 | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99247728; called by muse, mutect2
- GNA12 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs140322696; called by muse, mutect2, varscan2
- GPD1 | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755956209, COSV56548330; called by muse, mutect2, varscan2
- GPD1L | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56990540; called by muse, mutect2, varscan2
- GPR162 | c.1267C>T p.P423S (on ENST00000311268 / NM_019858.2; = p.P139S on NM_014449.2) | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.19); catalogued as COSV51834104; called by muse, mutect2, varscan2
- GPR32 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs893372939, COSV99567180; called by muse, varscan2
- GREB1 | c.2543A>G p.Y848C | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV52189580; called by muse, mutect2, varscan2
- GRM5 | c.2867C>T p.T956M (on ENST00000305447 / NM_001143831.2; = p.T924M on NM_000842.4) | Missense Mutation (SNP) | VAF 158/376 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.482); catalogued as rs1193446284, COSV59591456; called by muse, mutect2, varscan2
- GSTA3 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99274533; called by muse, varscan2
- GTSE1 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV71889253; called by muse, mutect2, varscan2
- GUCA1C | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 84/356 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV51722254; called by muse, mutect2, varscan2
- GUCY2D | c.2878G>A p.V960M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs781010216, COSV54696753; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 88/271 reads (32%) | catalogued as COSV54945907; called by mutect2*, varscan2
- HACL1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 39/92 reads (42%) | catalogued as rs767014981, COSV58254975; called by muse, mutect2, varscan2
- HADHA | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV66107724; called by muse, mutect2, varscan2
- HAUS5 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs199712182, COSV52548305; called by muse, mutect2, varscan2
- HCRTR2 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs747025393, COSV100904351; called by muse, mutect2, varscan2
- HDAC11 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV55473600; called by muse, mutect2
- HDLBP | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs752747372, COSV51473267; called by muse, mutect2, varscan2
- HECA | c.465C>G p.N155K | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV62769664; called by muse, mutect2, varscan2
- HEPHL1 | c.3130A>G p.T1044A | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV59892817; called by muse, mutect2, varscan2
- HFM1 | c.2414C>T p.T805I | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV54029622; called by muse, mutect2, varscan2
- HHIP | c.1742A>G p.K581R | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV99667198; called by muse, mutect2
- HIBCH | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62892006; called by muse, mutect2
- HIVEP1 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254492230, COSV101045115; called by muse, mutect2, varscan2
- HLA-G | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as rs780775783, COSV64406040; called by muse, mutect2, varscan2
- HMCN1 | c.10611G>T p.E3537D | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV54908966; called by muse, mutect2, varscan2
- HMGB2 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 18/547 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs1053732931; called by muse, mutect2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 54/114 reads (47%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXD9 | c.668dup p.T224Nfs*48 | Frame Shift Ins (INS) | VAF 27/132 reads (20%) | catalogued as rs758440041; called by mutect2, pindel, varscan2
- HPSE | c.1042T>C p.Y348H | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV60987227; called by muse, mutect2
- HS3ST3B1 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 152/436 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as COSV62906765; called by muse, mutect2, varscan2
- HTT | c.9131C>T p.T3044M | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1248764175, COSV61863825; called by muse, mutect2, varscan2
- HYAL2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV63306393; called by muse, mutect2, varscan2
- IARS1 | c.3524A>G p.N1175S | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as rs1228122014, COSV65115800; called by muse, mutect2, varscan2
- IGHJ4 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 140/625 reads (22%) | PolyPhen benign (0.164); catalogued as rs373129548; called by muse, mutect2, varscan2
- IGSF3 | c.1976C>T p.T659M (on ENST00000369486 / NM_001007237.3; = p.T679M on NM_001542.4) | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs1190666169, COSV59591500; called by muse, mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 18/110 reads (16%) | catalogued as rs748943611; called by mutect2, varscan2
- IL1RL1 | c.1024C>A p.L342I | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV52117138; called by muse, mutect2, varscan2
- INPP4A | c.1912A>G p.T638A (on ENST00000074304 / NM_001134224.1; = p.T599A on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV50797873; called by muse, mutect2, varscan2
- INSR | c.1703A>G p.N568S | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57164800; called by muse, mutect2
- INTS10 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV67604461; called by muse, mutect2
- IPCEF1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368673715; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS2 | c.2411G>T p.S804I | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.571); catalogued as COSV65479258; called by muse, mutect2, varscan2
- ITGA1 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1381525453, COSV50884928; called by muse, mutect2, varscan2
- ITGA7 | c.2402G>A p.G801D (on ENST00000555728; = p.G757D on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs968147262, COSV57696452; called by muse, mutect2, varscan2
- ITGAV | c.1397+1G>A p.X466_splice | Splice Site (SNP) | VAF 55/193 reads (28%) | catalogued as rs1158489754, COSV53714098; called by muse, mutect2, varscan2
- ITGAV | c.2820+1G>A p.X940_splice | Splice Site (SNP) | VAF 62/162 reads (38%) | catalogued as COSV53714115; called by muse, mutect2, varscan2
- ITGAX | c.1276del p.R426Afs*20 | Frame Shift Del (DEL) | VAF 90/315 reads (29%) | catalogued as rs1316967675; called by mutect2, varscan2
- ITGB4 | c.2963C>A p.A988D | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV52327705; called by muse, mutect2, varscan2
- ITGB6 | c.1490T>C p.L497P | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.161); catalogued as COSV51795434; called by muse, mutect2, varscan2
- ITPR2 | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1254629109, COSV67270853; called by muse, mutect2, varscan2
- ITPR3 | c.5800G>A p.V1934M | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778613128, COSV65410890; called by muse, mutect2, varscan2
- JAM2 | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57258204; called by muse, mutect2, varscan2
- JMJD1C | c.5935C>A p.P1979T | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV59516075; called by muse, mutect2, varscan2
- JMJD1C | c.2999T>C p.V1000A | Missense Mutation (SNP) | VAF 149/392 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV59516081; called by muse, mutect2, varscan2
- JUP | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60278430; called by muse, mutect2
- KALRN | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53768208; called by muse, mutect2, varscan2
- KASH5 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV71358071; called by muse, mutect2, varscan2
- KBTBD12 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59679777; called by muse, mutect2
- KBTBD12 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV59679786; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCNH5 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750874924, COSV59752526; called by muse, mutect2, varscan2
- KCNH6 | c.1258T>C p.Y420H | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV59004377; called by muse, mutect2
- KCNH8 | c.570C>T p.N190= | Splice Region (SNP) | VAF 30/80 reads (38%) | catalogued as rs755255892, COSV60464776; called by muse, mutect2, varscan2
- KCNIP2 | c.265C>T p.R89W (on ENST00000356640 / NM_173191.3; = p.R104W on NM_014591.5) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53307590; called by muse, mutect2, varscan2
- KCNQ5 | c.1258A>G p.S420G | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV59662086, COSV59665050; called by muse, mutect2, varscan2
- KCNS3 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV58407475, COSV58409075; called by muse, mutect2, varscan2
- KCNV1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV52086704; called by muse, mutect2, varscan2
- KDM5B | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV52509034; called by muse, mutect2, varscan2
- KDM5D | c.4325G>A p.R1442Q | Missense Mutation (SNP) | VAF 133/174 reads (76%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs745892280, COSV58736669; called by muse, mutect2, varscan2
- KIAA0100 | c.4960-2A>G p.X1654_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | catalogued as COSV101197299; called by muse, mutect2, varscan2
- KIAA0753 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV63817822; called by muse, mutect2, varscan2
- KIAA1109 | c.6846G>A p.M2282I | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs776942417, COSV52677968; called by muse, mutect2, varscan2
- KIAA1217 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as rs1434182438; called by muse, mutect2
- KIAA1522 | c.172del p.H58Tfs*24 (on ENST00000373480 / NM_001198972.2; = p.H117Tfs*24 on NM_020888.3) | Frame Shift Del (DEL) | VAF 45/132 reads (34%) | catalogued as rs767600627; called by mutect2, pindel, varscan2
- KIF12 | c.815G>C p.S272T (on ENST00000640217; = p.S134T on NM_138424.1) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65117473; called by muse, mutect2, varscan2
- KIF13A | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52454662; called by muse, mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 145/517 reads (28%) | catalogued as rs1193021160; called by mutect2, pindel, varscan2
- KIF21B | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764120600, COSV59756476, COSV59759681; called by muse, mutect2, varscan2
- KLHL10 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV53172647; called by muse, mutect2
- KLHL32 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV65112430; called by muse, mutect2, varscan2
- KLHL32 | c.1578G>A p.W526* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV65112435; called by muse, mutect2, varscan2
- KLHL38 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.298); catalogued as rs368547076; called by muse, mutect2, varscan2
- KMT2D | c.9209T>C p.L3070P | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56452330, COSV56501210; called by muse, mutect2, varscan2
- KMT2D | c.4619A>G p.E1540G | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56452350; called by muse, mutect2, varscan2
- KNDC1 | c.3794G>T p.S1265I | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV58839758; called by muse, mutect2, varscan2
- KPRP | c.1538T>C p.L513P | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV64221958; called by muse, mutect2, varscan2
- KRT27 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56972181; called by muse, mutect2
- KRT6B | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 149/373 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs200778388; called by muse, mutect2, varscan2
- LAMC1 | c.3442G>A p.A1148T | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs370475033; called by muse, mutect2, varscan2
- LARP6 | c.1417A>G p.R473G | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as COSV54580567; called by muse, mutect2, varscan2
- LCE1A | c.55A>G p.K19E | Missense Mutation (SNP) | VAF 187/520 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as rs1488164383, COSV58727386; called by muse, mutect2, varscan2
- LCN12 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.5); catalogued as COSV65421888; called by muse, mutect2
- LCOR | c.2912A>G p.D971G | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV53716576; called by muse, mutect2, varscan2
- LETM1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 174/428 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1276162107, COSV57101898; called by muse, mutect2, varscan2
- LGR4 | c.1759A>G p.M587V | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV64864716; called by muse, mutect2, varscan2
- LHFPL6 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV65446807; called by muse, mutect2, varscan2
- LILRB1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as rs373135949, COSV100207051; called by muse, varscan2
- LILRB2 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58746185; called by muse, mutect2, varscan2
- LILRB5 | c.1502C>T p.A501V (on ENST00000449561 / NM_001081442.3; = p.A500V on NM_006840.5) | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs762519162, COSV100300805, COSV60258408; called by muse, mutect2, varscan2
- LIN7A | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV54022059; called by muse, varscan2
- LINS1 | c.1532A>T p.D511V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100130216; called by muse, mutect2, varscan2
- LMTK2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51997842; called by muse, mutect2, varscan2
- LNPK | c.357+2T>C p.X119_splice | Splice Site (SNP) | VAF 20/110 reads (18%) | catalogued as COSV55824529; called by muse, mutect2, varscan2
- LPAR2 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV68352293; called by muse, mutect2, varscan2
- LRIG3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57865430; called by muse, mutect2, varscan2
- LRIT2 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV60563392; called by muse, mutect2, varscan2
- LRP1 | c.6448C>T p.R2150W | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs36003223; called by muse, mutect2, varscan2
- LRP1B | c.10195G>T p.G3399C | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67234352; called by muse, mutect2, varscan2
- LRP2 | c.3932G>T p.R1311L | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as rs140748929, COSV55558262; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC49 | c.412T>G p.S138A | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV53011749; called by muse, mutect2, varscan2
- LRRIQ4 | c.1536G>T p.Q512H | Missense Mutation (SNP) | VAF 265/709 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52981323; called by muse, mutect2, varscan2
- LRTM1 | c.397A>G p.N133D | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.522); catalogued as COSV55548583; called by muse, mutect2, varscan2
- LSP1 | c.322del p.Q108Sfs*31 | Frame Shift Del (DEL) | VAF 69/158 reads (44%) | catalogued as rs752018434; called by mutect2, varscan2
- LYST | c.10697A>G p.Y3566C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV67708299; called by muse, mutect2
- MACF1 | c.14686del p.T4896Lfs*29 (on ENST00000372915; = p.T2829Lfs*29 on NM_012090.5) | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | catalogued as rs775539898; called by mutect2, pindel, varscan2
- MACF1 | c.14798A>G p.E4933G (on ENST00000372915; = p.E2866G on NM_012090.5) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV57119434; called by muse, mutect2, varscan2
- MAGEA1 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV63118753; called by muse, mutect2, varscan2
- MAGEE1 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV63910633; called by muse, mutect2
- MAGI1 | c.2819C>T p.T940M (on ENST00000402939 / NM_001033057.2; = p.T968M on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as rs757905500, COSV58331701; called by muse, mutect2, varscan2
- MANEA | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV62589866; called by muse, mutect2, varscan2
- MANEA | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62589874; called by muse, mutect2, varscan2
- MANEAL | c.625G>A p.A209T (on ENST00000373045 / NM_001113482.1; = p.P12= on NM_152496.2) | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as COSV61116141; called by muse, mutect2, varscan2
- MANF | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56528533; called by muse, mutect2, varscan2
- MAOB | c.510C>G p.N170K | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.618); catalogued as COSV65205729; called by muse, mutect2, varscan2
- MAP1B | c.3484A>G p.I1162V | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs901542815, COSV57100803; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749973937, COSV51601194; called by muse, mutect2, varscan2
- MARCHF6 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV56882730; called by muse, mutect2, varscan2
- MARF1 | c.4907C>A p.P1636H | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60024859; called by muse, mutect2, varscan2
- MAT2B | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as COSV55201074; called by muse, mutect2, varscan2
- MBOAT1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs113970071, COSV61125922; called by muse, mutect2, varscan2
- MCM6 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99919039; called by muse, mutect2
- MED12 | c.2791C>G p.R931G | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61343547, COSV61358685; called by muse, mutect2, varscan2
- MED12L | c.1011del p.G338Afs*4 | Frame Shift Del (DEL) | VAF 29/260 reads (11%) | catalogued as COSV56379857; called by mutect2, varscan2
- MED18 | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65790659; called by muse, mutect2, varscan2
- MEFV | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs483353019, COSV54823284; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- MEGF8 | c.6760C>T p.R2254C (on ENST00000251268 / NM_001271938.2; = p.R2187C on NM_001410.3) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs750817882, COSV52077225; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 48/100 reads (48%) | catalogued as rs745891632; called by mutect2, varscan2
- MFAP3 | c.1080T>G p.C360W | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.171); catalogued as COSV59456555; called by muse, mutect2, varscan2
- MGAT4C | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV59833717; called by muse, mutect2, varscan2
- MINAR1 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759948705, COSV59583795; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIPEP | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 150/896 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101193104; called by muse, varscan2
- MLXIPL | c.1315A>G p.T439A | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV57668711; called by muse, mutect2, varscan2
- MON1B | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs763233279, COSV50248435; called by muse, mutect2, varscan2
- MSLN | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs751744116, COSV53503298; called by muse, mutect2, varscan2
- MTCL1 | c.2302C>T p.R768W (on ENST00000306329 / NM_001378206.1; = p.R408W on NM_015210.4) | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200169088, COSV60407275; called by muse, mutect2, varscan2
- MTFR1L | c.80_82del p.R27del | In Frame Del (DEL) | VAF 24/133 reads (18%) | catalogued as rs761898452; called by pindel, varscan2
- MTMR3 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs755138094, COSV60305500; called by muse, mutect2, varscan2
- MTO1 | c.1289C>T p.A430V (on ENST00000370300 / NM_133645.3; = p.A405V on NM_012123.4) | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64774052; called by muse, mutect2, varscan2
- MUS81 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768086876, COSV57259687; called by muse, mutect2
- MYBPC3 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99920340; called by muse, mutect2, varscan2
- MYCBP2 | c.12761A>G p.H4254R (on ENST00000357337; = p.H4292R on NM_015057.5) | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV62023791; called by muse, mutect2, varscan2
- MYH13 | c.5186A>T p.N1729I | Missense Mutation (SNP) | VAF 108/408 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV52832144; called by muse, varscan2
- MYH7B | c.3376_3378del p.E1126del | In Frame Del (DEL) | VAF 31/160 reads (19%) | catalogued as rs762599007; called by pindel, varscan2
- MYLK | c.1552A>G p.S518G | Missense Mutation (SNP) | VAF 122/344 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.567); catalogued as rs1187068090, COSV60608146; called by muse, mutect2, varscan2
- MYO1F | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 94/199 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.657); catalogued as rs996910823, COSV57795952; called by muse, mutect2, varscan2
- MYOM2 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV50723442; called by muse, mutect2
- MYRIP | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56866803, COSV56871914; called by muse, mutect2, varscan2
- NAAA | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54432667; called by muse, mutect2, varscan2
- NAGLU | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023436, COSV56794776; called by muse, mutect2, varscan2
- NAV3 | c.731del p.K244Sfs*26 | Frame Shift Del (DEL) | VAF 11/132 reads (8%) | catalogued as rs35319232; called by mutect2, pindel
- NCAM2 | c.1480+1G>C p.X494_splice | Splice Site (SNP) | VAF 91/248 reads (37%) | catalogued as COSV53081602, COSV99522830; called by muse, mutect2, varscan2
- NCOR1 | c.4745C>T p.A1582V | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs200294041, COSV51996637; called by muse, mutect2, varscan2
- NDUFB10 | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1177050531, COSV51910234; called by muse, mutect2, varscan2
- NEB | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV51426439; called by muse, mutect2, varscan2
- NEFH | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV60218033; called by muse, mutect2, varscan2
- NELFE | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs566216256, COSV64812315; called by muse, mutect2, varscan2
- NES | c.3845G>A p.S1282N | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV63961420; called by muse, mutect2, varscan2
- NEU2 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.698); catalogued as COSV52093127; called by muse, mutect2
- NFASC | c.1166C>T p.A389V (on ENST00000339876 / NM_001378329.1; = p.A400V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV58368558; called by muse, mutect2, varscan2
- NFIX | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.129); catalogued as COSV62178163; called by muse, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 21/136 reads (15%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NHS | c.604T>C p.Y202H | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV66277057; called by muse, mutect2, varscan2
- NIPAL3 | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 169/432 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV50232681; called by muse, mutect2, varscan2
- NKX2-5 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234660; called by muse, mutect2
- NLRP10 | c.1419del p.H474Mfs*7 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as rs1162048820; called by mutect2, pindel, varscan2
- NLRP8 | c.350T>A p.V117D | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52589140; called by muse, mutect2, varscan2
- NLRX1 | c.937T>A p.S313T | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV52705808; called by muse, mutect2, varscan2
- NLRX1 | c.2108T>C p.L703P | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752216780, COSV52705826; called by muse, mutect2, varscan2
- NOC3L | c.1274del p.L425Yfs*3 | Frame Shift Del (DEL) | VAF 63/541 reads (12%) | catalogued as rs780830188; called by mutect2, pindel, varscan2
- NOL4 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 138/418 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV52350388; called by muse, mutect2, varscan2
- NOS3 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV52491063; called by muse, mutect2, varscan2
- NOXO1 | c.754C>A p.R252S (on ENST00000397280 / NM_172168.3; = p.R246S on NM_144603.4) | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.087); catalogued as COSV99936970, COSV99937034; called by muse, mutect2
- NR3C2 | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.051); catalogued as COSV60993118; called by muse, mutect2, varscan2
- NR4A3 | c.1660del p.R554Efs*13 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | catalogued as COSV58246009; called by mutect2, pindel, varscan2
- NRDE2 | c.268del p.R90Gfs*69 | Frame Shift Del (DEL) | VAF 54/404 reads (13%) | catalogued as rs1249617548, COSV62963847; called by mutect2, pindel, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | catalogued as rs1167519601; called by mutect2, pindel, varscan2
- NRM | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs368813038; called by muse, mutect2, varscan2
- NRXN2 | c.3472C>A p.P1158T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55455723; called by muse, mutect2
- NSUN4 | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 180/478 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV61063360; called by muse, mutect2, varscan2
- NTM | c.577del p.R193Gfs*23 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | catalogued as COSV66182764; called by mutect2, pindel, varscan2
- NTSR1 | c.1147T>C p.C383R | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65138860; called by muse, mutect2, varscan2
- NUAK2 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV100904052; called by muse, mutect2
- NUDT15 | c.350del p.N117Mfs*25 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs764525662; called by mutect2, varscan2
- NUF2 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 173/439 reads (39%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV54844313; called by muse, mutect2, varscan2
- NUF2 | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 56/470 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV54844333; called by muse, mutect2, varscan2
- NUMBL | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs746765421, COSV53285792; called by muse, mutect2
- NUP133 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs368257231; called by muse, mutect2, varscan2
- NUP153 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50451593, COSV50459312; called by muse, mutect2, varscan2
- NUP155 | c.521T>C p.V174A (on ENST00000231498 / NM_153485.3; = p.V115A on NM_004298.4) | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV51531048; called by muse, mutect2, varscan2
- NUP210 | c.2236T>C p.C746R | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54407981; called by muse, mutect2, varscan2
- NUP62 | c.1037A>G p.D346G | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV61312457; called by muse, mutect2, varscan2
- OAZ2 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as rs1394962184, COSV100386427; called by muse, mutect2, varscan2
- OBSCN | c.6134T>C p.V2045A | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.255); catalogued as COSV99477422; called by muse, mutect2
- OBSCN | c.11495A>G p.E3832G | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99477428; called by muse, mutect2
- ODR4 | c.999del p.D334Ifs*22 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | catalogued as rs776869231; called by mutect2, varscan2
- OR10A7 | c.92del p.F31Sfs*53 | Frame Shift Del (DEL) | VAF 74/487 reads (15%) | catalogued as rs756006463; called by mutect2, varscan2
- OR10G2 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 51/614 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV73390399; called by muse, mutect2
- OR10H1 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58472045; called by muse, mutect2, varscan2
- OR2AE1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1259119847, COSV60390463; called by muse, mutect2, varscan2
- OR2D2 | c.321del p.F107Lfs*11 | Frame Shift Del (DEL) | VAF 29/177 reads (16%) | catalogued as rs757801594; called by mutect2, pindel, varscan2
- OR4C13 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs1213582782, COSV73648796; called by muse, mutect2, varscan2
- OR4C16 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58942520; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR6K6 | c.938A>T p.N313I (on ENST00000368144; = p.N289I on NM_001005184.1) | Missense Mutation (SNP) | VAF 70/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63744342; called by muse, mutect2, varscan2
- OSBPL11 | c.588del p.F196Lfs*11 | Frame Shift Del (DEL) | VAF 24/188 reads (13%) | catalogued as rs1197042783; called by mutect2, varscan2
- OSBPL7 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs536701820, COSV50109850; called by muse, mutect2, varscan2
- OSMR | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV57086460; called by muse, mutect2, varscan2
- OSTN | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV59140281; called by muse, mutect2
- OTOGL | c.6568G>A p.V2190I (on ENST00000547103; = p.V2181I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV54018262, COSV54018323; called by muse, varscan2
- OTUB1 | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55362357; called by muse, mutect2, varscan2
- OTUD6A | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 92/117 reads (79%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs867118856, COSV57973685; called by muse, mutect2, varscan2
- P2RX3 | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as COSV54443152; called by muse, mutect2, varscan2
- P4HB | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV58941898; called by muse, mutect2, varscan2
- PABPC1L | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53840954; called by muse, mutect2, varscan2
- PABPC1L | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53840963; called by muse, mutect2, varscan2
- PACS1 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); catalogued as COSV100270015; called by muse, mutect2
- PAMR1 | c.1430A>G p.D477G (on ENST00000619888 / NM_001001991.3; = p.D494G on NM_015430.4) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53516195, COSV99552578; called by muse, mutect2
- PAXBP1 | c.1994A>C p.E665A | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV51609780; called by muse, mutect2, varscan2
- PCDH9 | c.2299C>A p.L767I | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.04); catalogued as rs760054864, COSV60559670; called by muse, mutect2, varscan2
- PCED1A | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV62313804; called by muse, mutect2, varscan2
- PCID2 | c.625A>G p.R209G | Missense Mutation (SNP) | VAF 81/670 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV55814073; called by muse, mutect2, varscan2
- PCM1 | c.2927T>C p.I976T | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.563); catalogued as COSV61517144; called by muse, mutect2, varscan2
- PDCD11 | c.2996C>T p.A999V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs1418429545, COSV63933142; called by muse, mutect2, varscan2
- PDCD6IP | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as COSV100218825; called by muse, mutect2
- PDE11A | c.1529G>T p.R510I | Missense Mutation (SNP) | VAF 396/1105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1331676552, COSV53697895; called by muse, mutect2, varscan2
- PDE4A | c.1269G>T p.E423D (on ENST00000380702 / NM_001111307.2; = p.E184D on NM_006202.3) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53357615; called by muse, mutect2, varscan2
- PDS5A | c.3874A>G p.I1292V | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1210424457, COSV100337360; called by muse, mutect2
- PDS5A | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57825645; called by muse, mutect2, varscan2
- PDZD2 | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99224910; called by muse, mutect2
- PER1 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57920205; called by muse, mutect2, varscan2
- PEX13 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV54370442; called by muse, mutect2, varscan2
- PEX2 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 112/413 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs747866716, COSV63813755; called by muse, mutect2, varscan2
- PEX6 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs780239941, COSV55103741; called by muse, mutect2
- PGBD5 | c.1347G>T p.E449D (on ENST00000525115; = p.E518D on NM_001258311.2) | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV58412177; called by muse, mutect2, varscan2
- PGPEP1 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs565908679, COSV53252504; called by muse, mutect2, varscan2
- PHF2 | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100823138; called by muse, mutect2
- PHF3 | c.930A>C p.E310D | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV50322132; called by muse, mutect2, varscan2
- PHKA2 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 79/108 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66054534; called by muse, mutect2, varscan2
- PID1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV67428906; called by muse, mutect2, varscan2
- PIEZO2 | c.7552A>G p.I2518V | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV53290698; called by muse, mutect2, varscan2
- PIK3C3 | c.1597A>G p.K533E | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as COSV56280687; called by muse, mutect2
- PIWIL2 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 146/514 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV63252179; called by muse, varscan2
- PKDREJ | c.1982T>C p.V661A | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs754888721, COSV53549994; called by muse, mutect2, varscan2
- PLAGL2 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV55788707; called by muse, varscan2
- PLB1 | c.1707del p.V570Sfs*6 | Frame Shift Del (DEL) | VAF 66/211 reads (31%) | catalogued as rs1425500581; called by mutect2, pindel, varscan2
- PLCB1 | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62056174; called by muse, mutect2, varscan2
- PLCL1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs760605252, COSV101407194, COSV70839842; called by muse, mutect2, varscan2
- PLEKHA7 | c.2845C>T p.R949W | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202220441; called by muse, mutect2, varscan2
- PLEKHH1 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as COSV61284415; called by muse, mutect2, varscan2
- PLEKHH2 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs768972903, COSV56756129; called by muse, mutect2, varscan2
- PLXNA1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52527874; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PLXNB2 | c.2987G>T p.S996I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV63782448; called by muse, mutect2, varscan2
- PNOC | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs763003120, COSV57283837; called by muse, mutect2, varscan2
- POLD1 | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.153); catalogued as rs765437818, COSV54530105, COSV54533248; ClinVar: uncertain significance; called by muse, varscan2
- POLD1 | c.2617T>C p.C873R | Missense Mutation (SNP) | VAF 132/345 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.093); catalogued as COSV54531294; called by muse, varscan2
- POLH | c.1226C>A p.S409Y | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64779851; called by muse, mutect2, varscan2
- POLN | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 131/379 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV67025828; called by muse, mutect2, varscan2
- POLR1B | c.2020A>G p.I674V | Missense Mutation (SNP) | VAF 134/358 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as COSV54499525; called by muse, mutect2, varscan2
- POLR3E | c.1456C>A p.L486M | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55401379; called by muse, mutect2, varscan2
- POLRMT | c.1157A>G p.Y386C | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV73933316; called by muse, mutect2, varscan2
- POMK | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58857631; called by muse, mutect2, varscan2
- POP1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100855813; called by muse, mutect2
- POTEH | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 164/224 reads (73%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.623); catalogued as rs529970437, COSV58883751; called by muse, mutect2, varscan2
- PPIL4 | c.138+2T>C p.X46_splice | Splice Site (SNP) | VAF 23/150 reads (15%) | catalogued as COSV53567616; called by muse, mutect2, varscan2
- PPP1R12C | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1224522177, COSV54738084; called by muse, mutect2, varscan2
- PPP1R16B | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs772118838, COSV55379050; called by muse, mutect2, varscan2
- PPP2CB | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55328819; called by muse, mutect2, varscan2
- PPP4C | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54221760, COSV54222990, COSV99661658; called by muse, mutect2, varscan2
- PRAMEF4 | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 163/440 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV52439175; called by muse, mutect2, varscan2
- PREP | c.1057C>T p.P353S (on ENST00000369110; = p.P419S on NM_002726.5) | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.411); catalogued as COSV64870636; called by muse, mutect2, varscan2
- PRICKLE1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1566082169, COSV100566121, COSV61545237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKAA1 | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); catalogued as COSV57184433; called by muse, mutect2, varscan2
- PRKAA1 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1412797330, COSV99713246; called by muse, mutect2
- PRKAB1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568377821, COSV57554896; called by muse, mutect2, varscan2
- PRKAR1A | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV62235838; called by muse, mutect2, varscan2
- PRPF4 | c.227A>C p.E76A (on ENST00000374198 / NM_001322267.2; = p.E77A on NM_004697.5) | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV65252875; called by muse, mutect2, varscan2
- PRRC2B | c.2368G>A p.V790I | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs201362040, COSV61938411; called by muse, mutect2, varscan2
- PRRG3 | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100948728, COSV64851159; called by muse, mutect2, varscan2
- PRSS12 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56607122; called by muse, mutect2, varscan2
- PRSS53 | c.1324A>G p.R442G | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV54924902; called by muse, mutect2, varscan2
- PSMC1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54321077; called by muse, mutect2, varscan2
- PTK2B | c.804A>T p.E268D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57758767; called by muse, mutect2, varscan2
- PTPN14 | c.1262T>C p.M421T | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); catalogued as rs771815955, COSV65284926; called by muse, mutect2, varscan2
- PTPN3 | c.2383-2A>C p.X795_splice | Splice Site (SNP) | VAF 79/323 reads (24%) | catalogued as COSV52701902, COSV52707038; called by muse, mutect2, varscan2
- PTPRB | c.4195T>C p.F1399L | Missense Mutation (SNP) | VAF 77/629 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV99717314; called by muse, varscan2
- PTPRK | c.846T>A p.N282K | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100949594, COSV63887921; called by muse, mutect2, varscan2
- PTPRM | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 113/325 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763977409, COSV59864639; called by muse, mutect2, varscan2
- PXDN | c.2463G>T p.W821C | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53228074; called by muse, mutect2, varscan2
- QRFPR | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 211/543 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV57677807; called by muse, mutect2, varscan2
- R3HDM2 | c.1649T>C p.L550P | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV61290091; called by muse, mutect2, varscan2
- RAB11B | c.41-2A>G p.X14_splice | Splice Site (SNP) | VAF 13/145 reads (9%) | catalogued as COSV60085845; called by muse, mutect2
- RAB11FIP2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 216/523 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV62925398; called by muse, mutect2, varscan2
- RAB5C | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs1366208306, COSV56791356; called by muse, mutect2, varscan2
- RABGGTA | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs745370644, COSV52861794, COSV99252957; called by muse, mutect2
- RAD51AP2 | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV67588271; called by muse, mutect2, varscan2
- RALGAPA2 | c.5221G>T p.G1741W | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52500735; called by muse, mutect2, varscan2
- RANBP2 | c.5338A>G p.I1780V | Missense Mutation (SNP) | VAF 127/330 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99312067; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as COSV52788172; called by muse, mutect2, varscan2
- RAP2B | c.200T>C p.M67T | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60257125; called by muse, mutect2, varscan2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs760908242; called by mutect2, varscan2
- RASGRF2 | c.2326T>G p.S776A | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV54131884; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 57/266 reads (21%) | catalogued as rs773370779, COSV99532335; called by mutect2, varscan2
- RBM22 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV52270768; called by muse, mutect2, varscan2
- RBM28 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56163502; called by muse, mutect2, varscan2
- RBMX2 | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59729433; called by muse, mutect2, varscan2
- RBMXL1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374309282; called by muse, mutect2, varscan2
- RELCH | c.3095A>G p.E1032G | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1255128745; called by muse, mutect2
- REST | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs867829350, COSV58360065; called by muse, mutect2, varscan2
- REV3L | c.4298C>T p.A1433V | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.107); catalogued as rs757298074, COSV62620101; called by muse, mutect2, varscan2
- RFPL4B | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.466); catalogued as COSV71437470; called by muse, mutect2, varscan2
- RMC1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1265896597, COSV52571118; called by muse, mutect2, varscan2
- RNASET2 | c.447-1G>A p.X149_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as rs1256084643, COSV50351674; called by muse, mutect2, varscan2
- RNF20 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757082884, COSV101206591, COSV66661379; called by muse, mutect2, varscan2
- RNF216 | c.1524+2T>C p.X508_splice (on ENST00000425013 / NM_207116.3; = p.X565_splice on NM_207111.4) | Splice Site (SNP) | VAF 15/116 reads (13%) | catalogued as COSV66291060; called by muse, mutect2, varscan2
- RNF40 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs770830631, COSV61215283; called by muse, mutect2, varscan2
- RP1L1 | c.6612G>T p.E2204D | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV66756409; called by muse, mutect2, varscan2
- RPL15 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV57140167; called by muse, mutect2, varscan2
- RSPO3 | c.760C>A p.Q254K | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV63150590; called by muse, mutect2, varscan2
- RYR2 | c.3544C>T p.L1182F | Missense Mutation (SNP) | VAF 18/554 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100767542; called by muse, mutect2
- RYR3 | c.7919G>A p.G2640E (on ENST00000389232; = p.G2641E on NM_001036.6) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV66794899; called by muse, mutect2, varscan2
- S100A5 | c.273_275del p.N91del | In Frame Del (DEL) | VAF 38/233 reads (16%) | catalogued as rs752535190; called by pindel, varscan2
- SALL4 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53852781; called by muse, mutect2, varscan2
- SAMD9 | c.1262A>G p.H421R | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV66076087; called by muse, mutect2, varscan2
- SCN11A | c.3587G>A p.G1196E | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745559210, COSV56572160; called by muse, mutect2, varscan2
- SCRN1 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54131467; called by muse, mutect2, varscan2
- SCUBE1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs776980765, COSV62613321; called by muse, mutect2
- SCUBE3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as rs776672878, COSV51456459; called by muse, mutect2, varscan2
- SCYL2 | c.2362G>A p.V788I | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs768181517, COSV62568149; called by muse, mutect2, varscan2
- SDHAF3 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV64491447; called by muse, mutect2, varscan2
- SECISBP2L | c.1413del p.K471Nfs*20 (on ENST00000559471 / NM_001193489.2; = p.K426Nfs*20 on NM_014701.4) | Frame Shift Del (DEL) | VAF 20/183 reads (11%) | catalogued as rs768725524; called by mutect2, varscan2
- SEMA3F | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs377363752; called by muse, mutect2, varscan2
- SEMA4A | c.754A>G p.S252G | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV61773054; called by muse, mutect2, varscan2
- SEMA4C | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.077); catalogued as rs766585970, COSV59691204; called by muse, mutect2, varscan2
- SEMA5A | c.2105C>A p.P702H | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66796018; called by muse, mutect2, varscan2
- SENP7 | c.90+2T>C p.X30_splice | Splice Site (SNP) | VAF 22/308 reads (7%) | catalogued as COSV100053098; called by muse, mutect2
- SERPIND1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53139191; called by muse, mutect2, varscan2
- SERPINE2 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 18/315 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99296690; called by muse, mutect2
- SETD3 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 257/694 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs529236070, COSV59285053; called by muse, mutect2, varscan2
- SETD5 | c.737A>G p.K246R | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as COSV56712830; called by muse, mutect2, varscan2
- SGCZ | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as rs1342150245, COSV66020833, COSV66053884; called by muse, mutect2, varscan2
- SGO1 | c.1564dup p.R522Kfs*29 (on ENST00000263753 / NM_001012410.5; = p.R253Kfs*29 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 15/99 reads (15%) | catalogued as rs772386209; called by mutect2, varscan2
- SH2D3C | c.1816G>T p.G606C (on ENST00000314830 / NM_170600.3; = p.G449C on NM_005489.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV59124747; called by muse, mutect2, varscan2
- SH3GL3 | c.725T>C p.M242T | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61057949; called by muse, mutect2, varscan2
- SH3TC1 | c.1150T>C p.S384P | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV55285646; called by muse, mutect2, varscan2
- SHANK2 | c.5462A>C p.Q1821P | Missense Mutation (SNP) | VAF 66/524 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53603076; called by muse, mutect2, varscan2
- SIM1 | c.491T>C p.M164T | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53493282; called by muse, mutect2, varscan2
- SIRT4 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV52541181; called by muse, mutect2, varscan2
- SIX1 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99903336; called by muse, mutect2
- SLC12A4 | c.342+2T>C p.X114_splice | Splice Site (SNP) | VAF 19/84 reads (23%) | catalogued as COSV57930996; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 48/145 reads (33%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC16A11 | c.671del p.P224Qfs*8 (on ENST00000308009; = p.P200Qfs*8 on NM_153357.3) | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs764036340; called by mutect2, varscan2
- SLC16A3 | c.1223_1225del p.F408del | In Frame Del (DEL) | VAF 28/223 reads (13%) | catalogued as rs749043257; called by pindel, varscan2
- SLC16A6 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100517376, COSV59177867; called by muse, mutect2, varscan2
- SLC17A2 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV55352712; called by muse, mutect2, varscan2
- SLC17A6 | c.86+2T>C p.X29_splice | Splice Site (SNP) | VAF 20/143 reads (14%) | catalogued as COSV54137543; called by muse, mutect2, varscan2
- SLC17A8 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 115/261 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs372830647, CM165409; called by muse, mutect2, varscan2
- SLC22A6 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs1328265782, COSV64560358; called by muse, mutect2, varscan2
- SLC37A2 | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1435032783, COSV53522819; called by muse, mutect2, varscan2
- SLC37A3 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58265873; called by muse, mutect2
- SLC38A11 | c.957dup p.I320Yfs*12 (on ENST00000409149 / NM_001351539.1; = p.I298Yfs*12 on NM_173512.2) | Frame Shift Ins (INS) | VAF 60/193 reads (31%) | catalogued as rs1261204474; called by mutect2, pindel, varscan2
- SLC38A11 | c.816del p.F272Lfs*13 (on ENST00000409149 / NM_001351539.1; = p.F250Lfs*13 on NM_173512.2) | Frame Shift Del (DEL) | VAF 97/291 reads (33%) | catalogued as rs1368693762; called by mutect2, pindel, varscan2
- SLC38A11 | c.466G>A p.A156T (on ENST00000409149 / NM_001351539.1; = p.A134T on NM_173512.2) | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as rs371409052; called by muse, mutect2, varscan2
- SLC4A3 | c.1526T>C p.I509T | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99812790; called by muse, mutect2
- SLC4A4 | c.2791A>G p.M931V (on ENST00000264485 / NM_001098484.3; = p.M887V on NM_003759.4) | Missense Mutation (SNP) | VAF 160/378 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52627422; called by muse, mutect2, varscan2
- SLC5A8 | c.1050A>G p.L350= | Splice Region (SNP) | VAF 95/243 reads (39%) | catalogued as COSV73310784; called by muse, mutect2, varscan2
- SLC7A4 | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60384451; called by muse, mutect2, varscan2
- SLFNL1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771200715, COSV57234401; called by muse, mutect2, varscan2
- SMAD1 | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV57471753; called by muse, mutect2, varscan2
- SMARCA4 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs751542188, COSV60798215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA5 | c.520+2T>C p.X174_splice | Splice Site (SNP) | VAF 56/250 reads (22%) | catalogued as COSV51645176; called by muse, mutect2, varscan2
- SMARCAL1 | c.812-1G>C p.X271_splice | Splice Site (SNP) | VAF 32/167 reads (19%) | catalogued as COSV61921599; called by muse, mutect2, varscan2
- SMU1 | c.1415T>C p.V472A | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV68139948; called by muse, mutect2, varscan2
- SNPH | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60589751; called by muse, mutect2
- SNU13 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV53238255; called by muse, mutect2, varscan2
- SNX11 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 132/350 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100821749; called by muse, varscan2
- SOCS5 | c.408G>T p.L136F | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV60605301; called by muse, mutect2, varscan2
- SORBS1 | c.2729C>A p.P910Q (on ENST00000361941 / NM_001034954.2; = p.P560Q on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV53354205, COSV53359404; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 56/246 reads (23%) | catalogued as rs1278336874; called by mutect2, varscan2
- SOX13 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 124/516 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99689945; called by muse, varscan2
- SP140 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 232/1064 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs757998046, COSV100613340; called by muse, varscan2
- SPACA9 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.961); catalogued as rs867602163, COSV53768221; called by muse, mutect2, varscan2
- SPATA7 | c.1541A>C p.N514T | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV50417769; called by muse, mutect2, varscan2
- SPEG | c.7748C>A p.P2583H | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100404416; called by muse, mutect2, varscan2
- SPHK2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759607232, COSV55338354; called by muse, mutect2, varscan2
- SPNS1 | c.703T>C p.F235L | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs1005381047, COSV57955194; called by muse, mutect2, varscan2
- SPOCK2 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as COSV58036966; called by muse, mutect2, varscan2
- SPON1 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1204840910, COSV100115803; called by muse, mutect2, varscan2
- SPP2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs755087069, COSV51445088, COSV51445732; called by muse, mutect2, varscan2
- SPTBN1 | c.148+2T>A p.X50_splice | Splice Site (SNP) | VAF 32/83 reads (39%) | catalogued as COSV63340508; called by muse, mutect2, varscan2
- SRL | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68423631; called by muse, mutect2, varscan2
- SRP72 | c.25dup p.V9Gfs*9 | Frame Shift Ins (INS) | VAF 62/164 reads (38%) | catalogued as rs763130641; called by mutect2, varscan2
- SRR | c.345A>C p.K115N | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100026998; called by muse, mutect2
- SSBP1 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 132/493 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54681384; called by muse, mutect2, varscan2
- ST14 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs760328016, COSV53834084; called by muse, mutect2, varscan2
- STAB1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV58738057; called by muse, mutect2, varscan2
- STAT5A | c.118A>T p.S40C | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV61807114; called by muse, mutect2, varscan2
- STIL | c.3190G>A p.A1064T | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54551034; called by muse, mutect2, varscan2
- STT3B | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 96/388 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV55502463, COSV55503426; called by muse, mutect2, varscan2
- STUB1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50198745; called by muse, mutect2, varscan2
- STX8 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV60492001; called by muse, mutect2, varscan2
- STYXL1 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV50389829; called by muse, mutect2, varscan2
- SULF1 | c.223dup p.A75Gfs*48 | Frame Shift Ins (INS) | VAF 38/192 reads (20%) | catalogued as rs747316268; called by mutect2, varscan2
- SULT1A2 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100187122; called by muse, mutect2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 48/185 reads (26%) | catalogued as rs770033147; called by pindel, varscan2
- SYCP1 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 69/570 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as COSV65698456; called by muse, mutect2, varscan2
- SYCP2L | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as COSV51654147; called by muse, mutect2, varscan2
- SYK | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65325305; called by muse, mutect2
- SYMPK | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs557692962, COSV55612642; called by muse, mutect2, varscan2
- SYNE1 | c.23207A>T p.D7736V (on ENST00000367255 / NM_182961.4; = p.D7665V on NM_033071.3) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV55010566; called by muse, mutect2, varscan2
- SYNE4 | c.740T>C p.L247S | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53324935; called by muse, mutect2, varscan2
- SYNPR | c.30del p.F10Lfs*18 | Frame Shift Del (DEL) | VAF 72/421 reads (17%) | catalogued as COSV99888757; called by mutect2, pindel, varscan2
- SYPL2 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63995029; called by muse, mutect2, varscan2
- TAB2 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV53853141; called by muse, mutect2, varscan2
- TANC1 | c.4579C>T p.P1527S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV55089754; called by muse, mutect2, varscan2
- TAS1R3 | c.1109G>A p.C370Y | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59563894; called by muse, mutect2, varscan2
- TASOR2 | c.199del p.R67Dfs*29 | Frame Shift Del (DEL) | VAF 50/171 reads (29%) | catalogued as rs1317158125; called by mutect2, pindel, varscan2
- TBC1D10B | c.2126C>T p.T709I | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99977079; called by muse, mutect2
- TBC1D16 | c.1241A>C p.E414A | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV60478625; called by muse, mutect2
- TBC1D31 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs746780529, COSV54867289; called by muse, mutect2, varscan2
- TBC1D9B | c.3212G>A p.R1071H (on ENST00000356834 / NM_198868.3; = p.R1054H on NM_015043.4) | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs185070653, COSV62282318; called by muse, mutect2, varscan2
- TBCK | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200673063, COSV56765396; called by muse, mutect2, varscan2
- TBPL2 | c.1116dup p.K373* | Frame Shift Ins (INS) | VAF 50/154 reads (32%) | catalogued as COSV99902970; called by mutect2, pindel, varscan2
- TBX2 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53599515; called by muse, mutect2, varscan2
- TCF7L2 | c.598del p.L200Sfs*25 (on ENST00000355995 / NM_001367943.1; = p.L177Sfs*25 on NM_030756.5) | Frame Shift Del (DEL) | VAF 74/206 reads (36%) | catalogued as rs778855667; called by mutect2, pindel, varscan2
- TDRD6 | c.2750del p.N917Ifs*2 | Frame Shift Del (DEL) | VAF 52/173 reads (30%) | catalogued as COSV60174471; called by mutect2, pindel, varscan2
- TENM2 | c.2254G>A p.G752R (on ENST00000518659 / NM_001122679.2; = p.G520R on NM_001080428.3) | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69133248; called by muse, mutect2, varscan2
- TEP1 | c.5566del p.V1856Lfs*45 | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | catalogued as rs746695887; called by mutect2, pindel, varscan2
- TET2 | c.2639A>G p.H880R | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs373659652; called by muse, mutect2, varscan2
- TFAP2A | c.1207T>C p.Y403H (on ENST00000482890; = p.Y395H on NM_001032280.3) | Missense Mutation (SNP) | VAF 19/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60232925; called by muse, mutect2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 298/474 reads (63%) | catalogued as rs782753958; called by mutect2, varscan2
- TGFB1I1 | c.185C>T p.T62M (on ENST00000394863 / NM_001042454.3; = p.T45M on NM_015927.4) | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as rs201803234, COSV62357871; called by muse, mutect2, varscan2
- TGIF2LX | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 246/305 reads (81%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV52214313; called by muse, mutect2, varscan2
- TGM5 | c.799G>A p.A267T (on ENST00000220420 / NM_201631.4; = p.A185T on NM_004245.4) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.62); catalogued as rs761166440, COSV55010442; called by muse, mutect2, varscan2
- THAP12 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 124/335 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs976162015, COSV52611064; called by muse, mutect2, varscan2
- THOC3 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 132/624 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54198556; called by mutect2, varscan2
- THOC5 | c.1496G>A p.G499D | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs1186605360, COSV63799248; called by muse, mutect2, varscan2
- THOP1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs560375676, COSV57017500; called by muse, mutect2, varscan2
- TIAF1 | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.013); catalogued as COSV62868332; called by mutect2, varscan2
- TIMP3 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.985); catalogued as rs773990898, COSV56664965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
557 further variants in this file (245 protein-altering or splice-affecting, 288 silent, 24 other) are not listed here.
